Surgical pathology report (de-identified scan), TCGA case TCGA-10-0926, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0926-01A (Primary Tumor).

[page 1 of 3]
COMMENT:

(A) OMENTUM TUMOR:
METASTATIC HIGH GRADE PAPILLARY SEROUS CARCINOMA.

(B) OMENTUM #2:
METASTATIC HIGH GRADE PAPILLARY SEROUS CARCINOMA.

(C) RIGHT OVARY AND TUBE:
HIGH GRADE PAPILLARY SEROUS CARCINOMA INVOLVING THE SURFACE OF
FALLOPIAN TUBE, THE SURFACE AND THE CORTEX OF THE OVARY (0.4 CM IN
GREATEST DIMENSION).

(D) UTERUS, LEFT TUBE AND LEFT OVARY:
HIGH GRADE PAPILLARY SEROUS CARCINOMA OF THE OVARY (8.0 CM IN
GREATEST DIMENSION)
THE TUMOR INVOLVING THE SURFACE AND THE WALL OF THE FALLOPIAN TUBE.
THE TUMOR INVOLVING THE SEROSA SURFACE OF THE UTERUS.
Cystically atrophic endometrium.
Cervix, Nabothian cyst.

(E) TUMOR:
MALIGNANT MIXED MULLERIAN TUMOR (MMMT). (SEE COMMENT)

Malignant mixed mullerian tumor (MMMT) is only found in Specimen E. The sarcoma component is approximately 10% of the entire tumor mass (slides E2, E3 Ad, and E5 [REDACTED]).

(A) OMENTUM TUMOR - A portion of yellow-pink omentum (15.0 x 10.0 x 2.0 cm)

[page 2 of 3]
with multiple firm nodules varying in size from 4.0 cm to 4.5 cm. Two sections are taken for frozen. Representative sections of the remaining submitted in four additional cassettes.

SECTION CODE: A1, A2, frozen section; A3-A6, representative sections of remaining omentum. A1 AD to A10 AD, additional sections of omentum. (B) OMENTUM #2 - A portion of pink-red omentum (6.0 x 5.0 x 2.0 cm) which is replaced by firm tumor. Representative sections are submitted in three cassettes B1-B3.

(C) RIGHT OVARY AND TUBE - An ovary (2.5 x 1.5 x 1.0 cm) and attached fallopian tube (7.0 cm in length and 0.5 cm in circumference). The cut surface of the ovary is unremarkable. Multiple pink-tan, slightly firm nodules are present in the mesosalpinx on the surface of the tubes and of the ovaries. The ovary and fallopian tube are submitted entirely in five cassettes as follows:

SECTION CODE: C1, C2, ovary; C3-C5, fallopian tube.

(D) UTERUS, LEFT TUBE AND LEFT OVARY - A uterus (7.0 cm from cervix to fundus, 3.0 cm from cornu to cornu and 3.0 cm in the AP diameter). The cervix is unremarkable. The endometrium is smooth and measures 0.1 cm. A small gray-tan, firm nodule (0.3 cm) is present underneath the endometrium. Scattered tumor nodules, the largest one measuring 1.8 cm in greatest diameter, are present on the serosa of the uterus.

A multicystic, focally papillary tumor (8.0 x 6.0 x 5.0 cm) replaces the left ovary. The fallopian tube is grossly unremarkable. It measures 6.0 cm in length and 0.5 cm in circumference. Tumor tissue is seen in the mesosalpinx. Representative sections are submitted in twelve cassettes as follows:

SECTION CODE: D1, D2, cervix; D3, anterior endometrium; D4, posterior endometrium; D5-D10, tumor and possible ovarian tissue; D11, D12, fallopian tube. D1 AD to D8 AD, additional sections of ovarian tumor.

(E) TUMOR - Multiple irregular, pink-red, focally necrotic soft tissue fragment (10.0 x 6.0 x 1.0 cm). Focal papillary areas identified. Representative sections submitted in three cassettes E1-E3, E1 AD to E8, Additional sections of tumor.

-----END OF REPORT-----

[page 3 of 3]
[REDACTED]

Case imported from legacy computer system. The format of this report does not match the original case. [REDACTED], the section 'SPECIMEN' may have been added.

DIAGNOSIS:

MALIGNANT CELLS IDENTIFIED
METASTATIC PAPILLARY ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY

[REDACTED]

SPECIMEN:

Ascitic Fluid

GROSS DESCRIPTION:

80 ml. bloody fluid, SPGR-1.027, CPR-3.4

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1688dfb9-14d4-435a-af1b-b58da1d88bf0 (TCGA-10-0926.B940B1B3-8278-400E-B43A-E7897E0361B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).